Somatic mutation profile of tumor specimen 0DKO7H from CCDI case PBBXBT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 5.2 years (1,914 days).
Specimen 0DKO7H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8032f970-dd9d-4fc6-b9ec-d281473a66c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKO73 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5cd31518-8dca-4d0a-8a6c-be18194d09cf

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL1 | c.731G>T p.S244I (on ENST00000340736 / NM_001008701.3; = p.S239I on NM_014921.5) | Missense Mutation (SNP) | VAF 269/544 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61567030; called by muse, mutect2, varscan2
- CNDP2 | c.1394C>T p.A465V | Missense Mutation (SNP) | VAF 301/693 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as rs559463515, COSV60840654; called by muse, mutect2, varscan2
- VSIG8 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 43/904 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV63653625; called by muse, mutect2
- DZIP3 | c.3484G>A p.V1162I | Missense Mutation (SNP) | VAF 46/1744 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2
- EBF1 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 364/916 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FZD1 | c.1711G>A p.A571T | Missense Mutation (SNP) | VAF 472/794 reads (59%) | SIFT tolerated (0.52); PolyPhen benign (0.021); called by muse, varscan2
- MUC5B | c.8557C>A p.L2853M | Missense Mutation (SNP) | VAF 327/710 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RAD21 | c.1518A>G p.P506= | Silent (SNP) | VAF 590/1312 reads (45%) | called by muse, mutect2, varscan2
- WRNIP1 | c.-60C>T | 5'UTR (SNP) | VAF 56/111 reads (50%) | catalogued as rs878887787; called by muse, mutect2, varscan2
